Somatic mutation profile of tumor specimen TCGA-IM-A420-01A (aliquot TCGA-IM-A420-01A-11D-A23M-08) from TCGA case TCGA-IM-A420, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 39.2 years (14,332 days).
Specimen TCGA-IM-A420-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7e591a7-6bcb-4326-a058-2883e96841e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IM-A420-10A (Blood Derived Normal), aliquot TCGA-IM-A420-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47fa99ac-034d-44a0-b997-26ec0158f491

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 3, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- IRS1 | c.1774T>G p.L592V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as COSV100524522; called by muse, mutect2, varscan2
- MYCBPAP | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100088258; called by muse, mutect2, varscan2
- ARHGAP27 | c.1488C>G p.T496= (on ENST00000428638 / NM_001282290.1; = p.T155= on NM_199282.3) | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100976525; called by muse, mutect2, varscan2
- MFSD14B | c.1179G>A p.G393= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV100942672; called by muse, mutect2
- TCFL5 | c.897A>G p.A299= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as rs1187767871, COSV99415865; called by muse, mutect2, varscan2
